Somatic mutation profile of tumor specimen TCGA-ND-A4WA-01A (aliquot TCGA-ND-A4WA-01A-12D-A28R-08) from TCGA case TCGA-ND-A4WA, project TCGA-UCS (Uterine Carcinosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mullerian mixed tumor; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen TCGA-ND-A4WA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2e8001b-99b0-4ed0-92f1-ed30cd041497.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ND-A4WA-10B (Blood Derived Normal), aliquot TCGA-ND-A4WA-10B-01D-A28U-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/982912ac-122c-46da-8935-5a3f358c48fb

The open-access MAF lists 57 somatic variants for this specimen: 48 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 8, Nonsense Mutation 4, Frame Shift Del 3, Splice Site 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GALC | c.1592G>A p.R531H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs200378205, CM990620, COSV54325031; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.3749G>A p.R1250Q | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs975856232, COSV56860358; called by muse, mutect2, varscan2
- ADCY2 | c.1411C>T p.R471W | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.757); catalogued as rs754041062, COSV57866829; called by muse, mutect2, varscan2
- CLEC12A | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.27); PolyPhen benign (0.048); catalogued as rs761984982, COSV58562718; called by muse, mutect2, varscan2
- FAM171B | c.836G>A p.R279H | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs369698664; called by muse, mutect2, varscan2
- FLNA | c.2570C>T p.T857M | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs1488268931, COSV61052525; called by muse, mutect2, varscan2
- IL2 | c.331G>A p.V111I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs756737575, COSV56985338, COSV56986744; called by muse, mutect2, varscan2
- MICAL1 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 70/107 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755389348, COSV62196184; called by muse, mutect2, varscan2
- OSTN | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 43/107 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770293345; called by muse, mutect2, varscan2
- PARP14 | c.2629G>A p.V877M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752297915, COSV71734343, COSV71735672; called by muse, mutect2, varscan2
- PCDH11X | c.226C>T p.R76* | Nonsense Mutation (SNP) | VAF 56/160 reads (35%) | catalogued as COSV53444655; called by muse, mutect2, varscan2
- PLCL1 | c.1886A>T p.E629V | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.9); catalogued as COSV99071929; called by muse, mutect2, varscan2
- PXN | c.372G>C p.Q124H | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV99936396; called by muse, mutect2, varscan2
- RRP1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs758930459; called by muse, mutect2
- SCN11A | c.1378C>G p.L460V | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV100181366; called by muse, mutect2, varscan2
- SLC7A3 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.082); catalogued as rs746011818, COSV53227129; called by muse, mutect2, varscan2
- SMC4 | c.1801G>C p.D601H | Missense Mutation (SNP) | VAF 72/114 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV61003969; called by muse, mutect2, varscan2
- SQSTM1 | c.634C>T p.R212C | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs201263163, CM146288; called by muse, mutect2, varscan2
- TMEM132D | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 90/104 reads (87%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs749108405, COSV70597865; called by muse, mutect2, varscan2
- TUBGCP5 | c.992T>C p.I331T | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1244904118; called by muse, mutect2, varscan2
- ZNF142 | c.3818A>G p.N1273S (on ENST00000411696 / NM_001379660.1; = p.N1073S on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.61); PolyPhen benign (0.012); catalogued as rs772583006; called by muse, mutect2, varscan2
- ZNF473 | c.2134C>T p.R712C | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs1350315911; called by muse, mutect2, varscan2
- ZNF585B | c.1313A>T p.Y438F | Missense Mutation (SNP) | VAF 16/206 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.958); catalogued as rs1365246758; called by muse, mutect2
- ZNF615 | c.1930C>T p.R644* | Nonsense Mutation (SNP) | VAF 96/140 reads (69%) | catalogued as rs761632834, COSV65033851; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2175G>C p.R725S | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ARHGAP35 | c.2988del p.R997Efs*30 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by mutect2, pindel, varscan2
- ARHGEF10L | c.2238G>T p.W746C | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASTN1 | c.3551G>T p.G1184V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ATP7A | c.4073A>C p.N1358T | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C1QTNF1 | c.295G>A p.G99R | Missense Mutation (SNP) | VAF 67/183 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CILK1 | c.419A>C p.K140T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSTF2 | c.584C>A p.T195K | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- FREM2 | c.523G>T p.V175F | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- KAT2B | c.196G>T p.G66* | Nonsense Mutation (SNP) | VAF 6/25 reads (24%) | called by muse, mutect2, varscan2
- LARP1B | c.2497C>T p.L833F | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MARF1 | c.467C>T p.S156F | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.876); called by muse, mutect2
- MRC2 | c.2491C>T p.R831C | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- NHS | c.4781A>G p.Y1594C | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRDC | c.3027+1G>T p.X1009_splice | Splice Site (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.5457del p.G1820Afs*7 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- RPS6KA6 | c.1456-2A>T p.X486_splice | Splice Site (SNP) | VAF 11/25 reads (44%) | called by muse, mutect2, varscan2
- SCN3A | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TK1 | c.435_436del p.V146Gfs*220 | Frame Shift Del (DEL) | VAF 18/95 reads (19%) | called by mutect2, pindel, varscan2
- TREX2 | c.683G>A p.S228N (on ENST00000334497; = p.S185N on NM_080701.3) | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUFM | c.1135C>A p.P379T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UMOD | c.1520A>C p.Y507S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP11 | c.1267G>T p.E423* (on ENST00000218348; = p.E380* on NM_001371072.1) | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | called by muse, mutect2, varscan2
- ZC3H6 | c.2972C>T p.A991V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- AKAP8L | c.720C>T p.G240= | Silent (SNP) | VAF 65/149 reads (44%) | catalogued as rs371825174; called by muse, mutect2, varscan2
- C3 | c.4671C>T p.D1557= | Silent (SNP) | VAF 15/27 reads (56%) | called by muse, mutect2, varscan2
- CYP4X1 | c.216T>C p.I72= | Silent (SNP) | VAF 36/77 reads (47%) | called by muse, mutect2, varscan2
- FAM47B | c.1380G>A p.S460= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs191392189, COSV61454046; called by muse, mutect2, varscan2
- H3C8 | c.189C>T p.I63= | Silent (SNP) | VAF 49/154 reads (32%) | called by muse, mutect2, varscan2
- PCSK9 | c.1779G>A p.E593= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs1453831826; called by muse, mutect2, varscan2
- RNMT | c.825A>G p.Q275= | Silent (SNP) | VAF 11/43 reads (26%) | called by muse, mutect2, varscan2
- SEMA3D | c.2181C>T p.L727= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as rs774367634; called by muse, mutect2, varscan2
- FAM155A | c.-2del | 5'UTR (DEL) | VAF 26/118 reads (22%) | called by mutect2, pindel, varscan2
